Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QR, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QR-01A (Primary Tumor).

[page 1 of 3]
Extemporaneous histological examination

- Gross pathology : biopsy of the pericardium measuring 2 cm in diameter.
- Extemporaneous histological examination : compatible appearance with an invasion by a thymoma B.
- Conventional histological examination : After thawing and fixation, confirmation diagnosis thymoma (1A) .

ICD O-3
Thymoma, type B3, malignant 8585/3
Site: Thymus C37.9
JW 4/2/14

Macroscopic examination :

2) Thymectomy

Thymectomy specimen weighing 117 g is addressed oriented . It measures 15 cm x 7 cm x 5 cm and it is bordered by a strip of pericardium measuring 8 x 5 cm and resection lung parenchyma 9 x 3 x 2.5 cm both also identified. Resection limits have been the identification of a color ink .

The tumor 9 cm x 6 cm. It is appearance " sweetbreads " revised its center by areas of necrosis , calcifications .

When cut , the tumor invades the pericardium over its entire thickness .

3) Grease under xiphoid two fragments of 0.8 and 1.1 cm.

4) Ganglion Barety : a node of 2.7 cm

5) High latérotrachéal Ganglion constituted firstly four ganglia 0.5 cm (5A) and secondly of a cystic lesion major axis of 2.5 cm , multilocular , with fleshy part , white (5B) .

Histopathological examination :

- The samples taken at the level of the thymic tumor is characterized by separated by thick fibrous septa and lobules mainly composed of cells of epithelial type . These polygonal cells often have a pseudo- squamous appearance and are

[page 2 of 3]
seat even some atypical mitosis . They have spaces around
perivascular light sometimes narrow , sometimes even expanded and cystic

- The samples taken at the level of the pulmonary parenchyma (2B) are
characterized by invasion of the lung by the thymic tumor. It invades
also the bronchial tree as an endoluminal mass .

- The samples taken at the pericardium (2G) are also the seat of a
pericardial thickened tumor invasion by the tumor.

The limits of tumor resection pass in tissue area 2A and lungs
pericardial .

- Fat sub xiphoid addressed separately (3) consists of a tissue of
cellulo- adipose seat of a node of normal appearance . Absence of tumor invasion .

- Among the laterotracheal top four nodes of 0.5 cm (5A) are
normal appearance. Absence of tumor invasion . Cystic lesion calculated separately
(5B) is thymic parenchyma partitioned by thick fibrous septa and
formed in its center is identical to that previously described proliferation . The
lesion is limited by a fibrous capsule . On the outskirts , we did not find any
normal glandular parenchyma preserved, which does not confirm the existence
a lymph node metastasis .

Immunohistochemical examination :

epithelial cells

- expression of CK19 , 7, 5/6

absence of expression of CK20 , the CD5 and CD20

[page 3 of 3]
Immature T lymphocytes type : CD1A + and CD99 +

Conclusion :

Thymoma subtype B3 -type measuring 9 cm by 6 cm.

Invasion of the pericardium and lung parenchyma. lymph node metastasis

Modified Masaoka classification : IVb

WHO classification : T4 N2 M0

electronic signature

Criteria	W 12/18/13	Yes	No

Source: NCI Genomic Data Commons file e86363b1-b440-4e1d-9737-73f27fe4d366 (TCGA-4V-A9QR.70B5468B-8FF8-4959-931D-669CF01D85BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).